Surgical pathology report (de-identified scan), TCGA case TCGA-PL-A8LV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Institute of Human Virology Nigeria, specimen TCGA-PL-A8LV-01A (Primary Tumor).

[page 1 of 2]
Age:

Sex: Female

Tissue Source Site (TSS):

Date of Tumour Procurement:

ICD O-3
Carcinoma, medullary 8510/3
Site @ Breast NOS C50.9
JP 5/19/14

1. **GROSS ASSESSMENT:** Cut section showed a variegated tumour. 5x3x2cm,
No lymph nodes.

2. MICROSCOPIC ASSESSMENT

Microscopic description: Section shows a necrotic and invasive tumour growing in trabecular, cords, syncytium, solid nests and trabecular patterns. It is composed of large cells having pleomorphic hyperchromatic nuclei and amphophilic cytoplasm. The stroma is desmoplastic containing similar tumour cells and aggregates of lymphocytes

3. **Tumour Type:** Malignant
4. **Tumour Site:** Right Breast
5. **Distance of invasive carcinoma to closest margin:** 3mm
- Which margin? Deep resection

[page 2 of 2]
TSS Unique patient ID:

6. **HISTOLOGICAL DIAGNOSIS:** Medullary Adenocarcinoma

7. **COMMENTS:** Nuclear score:3, Pathological TNM stage: pT2

Dr

Reporting Pathologist Name

Signature

Date

Primary Tumor Discrepancy		✓

Source: NCI Genomic Data Commons file f977205d-2ebb-4f2a-b7ff-f6edeb977aeb (TCGA-PL-A8LV.D35DBECD-5241-4562-85CC-2822BB338279.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).